Somatic mutation profile of tumor specimen 0DMKL2 from CCDI case PBCALJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroepithelioma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 11.4 years (4,170 days).
Specimen 0DMKL2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58adaad4-25b2-41d9-903a-d3f27d03aa7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKKL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/795ccb92-20cb-4162-bea8-22f16ecc276a

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LONP1 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 34/415 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs930763241, COSV100638610; called by muse, mutect2
- SLC10A3 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 69/312 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782603843, COSV54837767; called by muse, mutect2, varscan2
- FGF12 | c.578A>G p.K193R (on ENST00000454309 / NM_021032.5; = p.K131R on NM_004113.6) | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); called by muse, mutect2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 26/574 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 8/58 reads (14%) | called by muse, varscan2
- DLX6 | c.-54G>A | 5'UTR (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- GABRG2 | c.548+75T>A | Intron (SNP) | VAF 4/45 reads (9%) | catalogued as rs1317696404; called by muse, varscan2
- TMC7 | c.2106+240del | Intron (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
